Somatic mutation profile of tumor specimen TARGET-50-PAJPDC-01A (aliquot TARGET-50-PAJPDC-01A-01D) from TARGET case TARGET-50-PAJPDC, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 8.0 years (2,904 days).
Specimen TARGET-50-PAJPDC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c3133e7-287d-4c8d-96e1-bdae91a6c0e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJPDC-10A (Blood Derived Normal), aliquot TARGET-50-PAJPDC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0398a262-dbb5-4ea7-a63e-dfeb8dac7a6c

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Ins 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB5 | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 213/744 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56669233, COSV56674827; called by muse, mutect2, varscan2
- CARD10 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs753304481, COSV52654931; called by muse, mutect2, varscan2
- CCER1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs371760411, COSV62646253; called by muse, mutect2, varscan2
- CDC73 | c.1560-1G>T p.X520_splice | Splice Site (SNP) | VAF 366/541 reads (68%) | catalogued as COSV66465583; called by muse, mutect2, varscan2
- DNHD1 | c.13267G>A p.V4423M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1422055452, COSV54432019; called by muse, mutect2, varscan2
- GTF2H3 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 266/718 reads (37%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as COSV57460367; called by muse, varscan2
- HOMEZ | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs1457228340; called by muse, mutect2
- KHDRBS3 | c.762C>G p.Y254* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV63415713; called by muse, mutect2, varscan2
- MTMR3 | c.2233C>G p.L745V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs760984166, COSV60302512; called by muse, mutect2, varscan2
- ABCA13 | c.14885A>G p.N4962S | Missense Mutation (SNP) | VAF 34/510 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2
- AFDN | c.2736G>C p.E912D | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); called by muse, mutect2
- CACHD1 | c.2086_2087dup p.L697Afs*10 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel
- EEF1AKMT4-ECE2 | c.2162A>T p.E721V | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSDMC | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.469); called by muse, mutect2
- MAMDC4 | c.2682C>A p.H894Q (on ENST00000445819; = p.H815Q on NM_206920.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.996); called by muse, varscan2
- GOLGA4 | c.294C>T p.S98= | Silent (SNP) | VAF 158/170 reads (93%) | called by muse, mutect2, varscan2
- IGKV3D-11 | c.39C>G p.L13= | Silent (SNP) | VAF 73/270 reads (27%) | called by muse, mutect2, varscan2
- MAST1 | c.954G>A p.T318= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs751945653, COSV52242751; called by muse, mutect2, varscan2
- RSF1 | c.1275T>C p.C425= | Silent (SNP) | VAF 46/509 reads (9%) | catalogued as COSV57837460; called by muse, mutect2
